Surgical pathology report (de-identified scan), TCGA case TCGA-V3-A9ZX, project TCGA-UVM (Uveal Melanoma), tissue source site Cleveland Clinic Foundation, specimen TCGA-V3-A9ZX-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

ADDITIONAL PROCEDURES PRESENT

Patient Name: [REDACTED]

Specimen #: [REDACTED]

Patient ID #: [REDACTED]

Date of Procedure:

DOB: [REDACTED]

Date of Receipt:

Client: [REDACTED]

Date of Report:

Physician(s): [REDACTED]

Location:

SPECIMEN SUBMITTED

A: LEFT EYE

FINAL DIAGNOSIS

Left eye, enucleation - Malignant ciliochoroidal melanoma, epithelioid and spindle cell type.
- See synoptic report for summary of key pathologic findings.

SYNOPTIC REPORT OF KEY PATHOLOGIC FINDINGS

LEFT EYE:

Procedure:

Enucleation

Specimen Size:

For Enucleation

Anteroposterior diameter: 20.8 mm

Horizontal diameter: 23.8 mm

Vertical diameter: 22.0 mm

Length of optic nerve: 8.9 mm

For Enucleation-Diameter of optic nerve 3.5 mm (Slide measurement)

Specimen Laterality:

Left

Tumor Site (macroscopic examination/transillumination):

Superotemporal quadrant of globe

Tumor Location After Sectioning:

Distance from anterior edge of tumor to limbus at cut edge: 1 mm

Distance of posterior margin of tumor base from edge of optic disc: 5 mm

Tumor Involvement of Other Ocular Structures:

Sclera

Choroid

Ciliary body

Histologic Type:

Mixed cell type

Histopathologic Type:

Mixed cell melanoma (>10% epithelioid cells and <90% spindle cells)

Histologic Grade (pG):

ICD-O-3

Melanoma, epithelioid & spindle cell mixed 8770/3

S. ita. Overlapping lesion of eye

Radney C698

4/22/14

[page 2 of 3]
Surgical Pathology Report (continued)

pG2: Mixed cell melanoma
Tumor Size After Sectioning:
Base at cut edge: 11.5 mm
Greatest height: 8.1 mm
Tumor Location:
Anterior margin between equator and iris
Scleral Involvement:
Intrascleral
Margins:
No melanoma at margins
Growth Pattern:
Solid mass
Primary Tumor (pT):
Iris:
Not Applicable
Ciliary Body and Choroid:
pT2b: Tumor size category 2 with ciliary body involvement
Regional Lymph Nodes (pN):
pNX: Regional lymph nodes cannot be assessed
Distant Metastasis (pM):
Not applicable
Additional Pathologic Findings:
+Mitotic rate: 35 per 40 high power fields (Field Diameter=0.55mm)
Extravascular matrix pattern (PAS stain): Present
Degree of pigmentation
+mild
+Macrophages
+few
+Tumor infiltrating lymphocytes
+many
Retinal detachment
Hemorrhage
Other: Cataract

Electronic Signature

ADDITIONAL PROCEDURE(S)

DNA Extraction

Date Ordered:

Date Reported: PENDING

CLINICAL DATA
CHOROIDAL MELANOMA

GROSS DESCRIPTION

A. Received fresh labeled is a left eye measuring 22.0 mm superoinferiorly, 20.8 mm anteroposteriorly, and 23.8 mm horizontally. The globe is round in shape. An 8.9 mm length of optic nerve is present. The cornea is surgically absent. The thin rim of remaining cornea is transparent and measures 8.9 mm superoinferiorly, and 11.4 mm

[page 3 of 3]
Surgical Pathology Report (continued)

horizontally. The sclera is smooth and glistening. Transillumination of the globe does reveal a shadow extending from 9:00 to 12:00. The globe is opened in a superior inferior meridian fashion to reveal a red-brown firm mass. The mass measures 8.1 mm in height and 11.5 mm in basal diameter. The mass does appear to grossly involve the choroid, ciliary body, iris, and retina. The sclera and optic nerve appear uninvolved. A lens is present. The specimen is totally submitted as follows: A1 superior calotte, A2 pupil optic nerve section, A3 inferior calotte, A4 optic nerve shave margin.

Criteria	lw 1/30/14	Yes	No

END OF REPORT

Page 3 of 3
Print Date:

Source: NCI Genomic Data Commons file ceb793a4-bcdc-4b1b-baad-a8c4cb019b63 (TCGA-V3-A9ZX.CB5480FC-4BE1-478D-BEB5-39D74FD3F2E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).